Somatic mutation profile of tumor specimen TCGA-LA-A7SW-01A (aliquot TCGA-LA-A7SW-01A-11D-A401-08) from TCGA case TCGA-LA-A7SW, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.5 years (26,116 days).
Specimen TCGA-LA-A7SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca986d23-ddbe-4e08-b883-5437fc7779a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LA-A7SW-10A (Blood Derived Normal), aliquot TCGA-LA-A7SW-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b989b3d9-9663-4a04-a482-7977a1ec6c89

The open-access MAF lists 101 somatic variants for this specimen: 74 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 25, Nonsense Mutation 5, In Frame Del 2, Splice Site 2, Nonstop Mutation 1, Frame Shift Ins 1, Intron 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP10 | c.869T>G p.L290R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV56733653, COSV99855310; called by muse, mutect2, varscan2
- ALAS2 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100238097; called by muse, mutect2
- ANGEL1 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99200339; called by muse, mutect2, varscan2
- ANKRD35 | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100841658; called by muse, mutect2, varscan2
- APBA2 | c.1621A>C p.K541Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV101258134, COSV67104190; called by muse, mutect2, varscan2
- ATG4A | c.988T>C p.F330L | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV100563607; called by muse, mutect2, varscan2
- AUTS2 | c.3677C>A p.T1226K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100715560, COSV61397940; called by muse, mutect2
- BCLAF1 | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); catalogued as COSV100786464; called by muse, mutect2, varscan2
- C10orf99 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV100929347; called by muse, mutect2
- CCSER1 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as rs1366957887, COSV100388899; called by muse, mutect2, varscan2
- CDC14B | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs144589840; called by muse, mutect2, varscan2
- CLINT1 | c.1364C>G p.P455R | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99753588; called by muse, mutect2
- CLMP | c.1054A>C p.N352H | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV101507385; called by muse, mutect2, varscan2
- CNTNAP2 | c.2991T>G p.D997E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.074); catalogued as COSV100663928; called by muse, mutect2, varscan2
- COL14A1 | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770642323, COSV52860923; called by muse, mutect2, varscan2
- DOCK8 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771753565, COSV66635615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DQX1 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101098836; called by muse, mutect2, varscan2
- DRD3 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99879246; called by muse, mutect2, varscan2
- E2F4 | c.591G>C p.K197N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100103648; called by muse, mutect2
- ENOSF1 | c.242A>T p.D81V (on ENST00000340116 / NM_001354066.2; = p.D33V on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99200990; called by muse, mutect2, varscan2
- FBXW10 | c.2693C>T p.S898F | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57060598; called by muse, mutect2, varscan2
- FSHR | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 99/320 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV100436745; called by muse, mutect2, varscan2
- GABRB1 | c.921T>A p.D307E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99780617; called by muse, mutect2, varscan2
- GDF9 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV99737189; called by muse, mutect2, varscan2
- GLRA3 | c.588G>C p.M196I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); catalogued as rs1451315274, COSV99927185, COSV99927798; called by muse, mutect2, varscan2
- GPRIN1 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs201438977, COSV56139909; called by muse, mutect2, varscan2
- IGHG2 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs772444756; called by muse, mutect2, varscan2
- IPO5 | c.2797G>C p.A933P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV55151854, COSV99847067; called by muse, mutect2, varscan2
- ISG20L2 | c.657dup p.C220Lfs*63 | Frame Shift Ins (INS) | VAF 11/80 reads (14%) | catalogued as rs1326791623; called by mutect2, pindel, varscan2
- ITPR2 | c.4684C>G p.L1562V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as COSV101189876, COSV67269442; called by muse, mutect2, varscan2
- KRAS | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV56097943, COSV99771147; called by muse, mutect2, varscan2
- LAMB3 | c.2230G>C p.D744H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV100620170; called by muse, mutect2, varscan2
- LIMA1 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs994395012, COSV100372296; called by muse, mutect2, varscan2
- MPP3 | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV101263304, COSV68197399; called by muse, mutect2, varscan2
- MYH10 | c.4462C>G p.L1488V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as rs762499918, COSV99344473; called by muse, mutect2, varscan2
- MYSM1 | c.947T>G p.F316C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101284027; called by muse, mutect2, varscan2
- NBPF1 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 62/695 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV101236255; called by muse, mutect2, varscan2
- NPHS1 | c.2974C>A p.P992T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100799654; called by muse, mutect2, varscan2
- NUDCD1 | c.928C>G p.H310D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV99516830, COSV99517222; called by muse, mutect2, varscan2
- PCDH15 | c.4690A>T p.K1564* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as rs778486965, COSV100903432; called by muse, mutect2, varscan2
- PIEZO2 | c.8224A>G p.T2742A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53287155, COSV99554639; called by muse, mutect2, varscan2
- PPAT | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99947123; called by muse, mutect2, varscan2
- PPP1R12B | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766756633; called by muse, mutect2, varscan2
- PRAMEF19 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 63/341 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs754660509, COSV65819448; called by muse, mutect2, varscan2
- RBM46 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99907952; called by muse, mutect2
- RIN1 | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV100254425, COSV60929181; called by muse, mutect2, varscan2
- SACS | c.10184T>A p.L3395* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101207248; called by muse, mutect2, varscan2
- SBF2 | c.4720G>A p.V1574I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186823023; called by muse, mutect2
- SLC2A13 | c.944G>T p.R315I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99786148; called by muse, mutect2, varscan2
- SLC41A2 | c.785T>A p.L262* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99316263; called by muse, mutect2, varscan2
- SLC5A4 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as rs140177779; called by muse, varscan2
- SLC6A14 | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100903089, COSV100903219; called by muse, mutect2
- SPAG1 | c.1989-1G>C p.X663_splice | Splice Site (SNP) | VAF 14/163 reads (9%) | catalogued as COSV99308581; called by muse, mutect2
- SPEF2 | c.4355G>A p.R1452H | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as rs753560017, COSV57431079; called by muse, mutect2, varscan2
- SYNGAP1 | c.3929C>T p.T1310M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs796430835, COSV99538062; called by muse, varscan2
- TAF1L | c.3113A>C p.K1038T | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.423); catalogued as COSV54256364, COSV54266410; called by muse, mutect2, varscan2
- TFR2 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV99355471; called by muse, mutect2, varscan2
- THAP3 | c.266A>G p.Q89R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.631); catalogued as rs1392826603, COSV99275515; called by muse, mutect2, varscan2
- TLN2 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV100168336; called by muse, mutect2, varscan2
- TMCO4 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 114/269 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs146596460; called by muse, mutect2, varscan2
- TPH2 | c.479A>C p.E160A | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100421961; called by muse, mutect2, varscan2
- TTN | c.73129G>A p.G24377S (on ENST00000591111; = p.G16953S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV100600203; called by muse, mutect2, varscan2
- UBQLN2 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.776); catalogued as COSV100592645; called by muse, mutect2, varscan2
- USP53 | c.2655_2657del p.I885del | In Frame Del (DEL) | VAF 34/64 reads (53%) | catalogued as rs757401193; called by mutect2, pindel, varscan2
- ZNF154 | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101377461; called by muse, mutect2, varscan2
- ZNF586 | c.1142C>G p.S381* | Nonsense Mutation (SNP) | VAF 22/152 reads (14%) | catalogued as rs1237302527, COSV101197629, COSV66972317; called by muse, mutect2
- ZNF600 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.846); catalogued as rs368067969, COSV100592926; called by muse, mutect2, varscan2
- ZNF761 | c.754A>C p.N252H | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV100483294; called by muse, mutect2, varscan2
- C1orf56 | c.1012_*4del | Nonstop Mutation (DEL) | VAF 18/156 reads (12%) | called by mutect2, pindel
- CACNA1G | c.326_331del p.C109_D110del | In Frame Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- IGKV1D-13 | c.83A>G p.Q28R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SLC15A1 | c.1682_1683+1del p.X561_splice | Splice Site (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- TP53 | c.19_52del p.D7Hfs*26 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel
- XAGE2 | c.46A>C p.S16R | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.06); called by muse, mutect2
- AGBL1 | c.2571G>A p.L857= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV101222282, COSV101222383; called by muse, mutect2
- ATP9A | c.732C>T p.S244= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as rs557141465, COSV58763943; called by muse, mutect2, varscan2
- CDHR3 | c.2199A>G p.L733= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs765831356, COSV100488090; called by muse, mutect2, varscan2
- CEMIP2 | c.2601A>C p.P867= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV100987081; called by muse, mutect2, varscan2
- CSMD1 | c.4377A>C p.P1459= (on ENST00000520002; = p.P1458= on NM_033225.6) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1179301292, COSV100145185; called by muse, mutect2
- E2F2 | c.438C>T p.S146= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs752519863, COSV100674709; called by muse, mutect2, varscan2
- FAM120B | c.102T>C p.Y34= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs1380049565, COSV99379087; called by muse, mutect2, varscan2
- GRM3 | c.843G>A p.S281= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100862169, COSV64468578; called by muse, mutect2, varscan2
- GRM8 | c.1938C>T p.I646= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100281398, COSV100286800; called by muse, mutect2, varscan2
- HUS1B | c.261G>T p.L87= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100033180, COSV57869097; called by muse, mutect2
- INVS | c.1671C>A p.I557= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as COSV52441505, COSV99317238; called by muse, mutect2, varscan2
- KAZN | c.984C>T p.G328= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs1338386064, COSV63209231; called by muse, mutect2, varscan2
- MTHFD1 | c.1347C>T p.I449= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV99386650; called by muse, mutect2, varscan2
- OR56A4 | c.885G>T p.T295= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs199866327, COSV58110424; called by muse, mutect2
- POLR1A | c.879T>C p.N293= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV99807262; called by muse, mutect2, varscan2
- PPP4R1 | c.2304A>G p.L768= (on ENST00000400556 / NM_001042388.3; = p.L751= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV99553261; called by muse, mutect2, varscan2
- PRR5 | c.210C>T p.G70= (on ENST00000336985 / NM_181333.4; = p.G61= on NM_015366.4) | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs935924832, COSV99134127; called by muse, mutect2
- RASAL3 | c.741G>T p.R247= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100640271; called by muse, mutect2, varscan2
- SLC17A9 | c.240C>T p.G80= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs1056272564, COSV64847194; called by muse, mutect2, varscan2
- SLC5A4 | c.810G>A p.V270= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV99831757; called by muse, varscan2
- SPRTN | c.1092C>G p.V364= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs764047906, COSV99149537; called by muse, mutect2, varscan2
- SVIL | c.978C>T p.S326= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1382087354, COSV100881078; called by muse, mutect2, varscan2
- UGGT2 | c.4260A>G p.P1420= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as COSV100948523; called by muse, mutect2
- WDR49 | c.1110T>C p.N370= (on ENST00000308378 / NM_001366158.1; = p.N711= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100392032; called by muse, mutect2, varscan2
- ZNF638 | c.3597T>C p.A1199= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100038236; called by muse, mutect2, varscan2
- GULP1 | c.-172+4428G>C | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100770318; called by muse, mutect2
- MIR92A1 | n.9A>G | RNA (SNP) | VAF 30/307 reads (10%) | catalogued as rs756016604; called by muse, mutect2, varscan2
